Somatic mutation profile of tumor specimen MBCProject_0744_T1_WES (aliquot MBCProject_0744_T1_WES_1) from CMI case MBCProject_0744, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Tissue or organ of origin: Breast, NOS.
Specimen MBCProject_0744_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2eb6c199-520d-4409-85f5-9bfc52ab1d05.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0744_SALIVA (Saliva), aliquot MBCProject_0744_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd17d336-eba0-42f1-aa99-86cea98a5e1b

The open-access MAF lists 37 somatic variants for this specimen: 25 protein-altering or splice-affecting, 4 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Intron 6, Silent 4, 3'UTR 2, Frame Shift Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2264T>C p.L755S | Missense Mutation (SNP) | VAF 34/124 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913470, COSV54062780, COSV54064269; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ERBB3 | c.2783A>G p.E928G | Missense Mutation (SNP) | VAF 54/191 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57248104, COSV99031563; called by muse, mutect2, varscan2
- CDK12 | c.2351G>A p.R784Q | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.023); catalogued as rs191899574; called by muse, mutect2, varscan2
- INSIG1 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 85/464 reads (18%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.025); catalogued as rs1313501864; called by muse, mutect2, varscan2
- KCNC1 | c.103G>T p.A35S | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.166); catalogued as rs779700926; called by muse, mutect2, varscan2
- KIFC3 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.089); catalogued as rs1555608470, COSV65552025; called by muse, mutect2, varscan2
- NLRC5 | c.3160C>T p.R1054W | Missense Mutation (SNP) | VAF 75/285 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as rs768811851, COSV52650051; called by muse, mutect2, varscan2
- NOTCH4 | c.4190C>T p.P1397L | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.095); catalogued as rs753178549, COSV100900675, COSV66681461; called by muse, mutect2, varscan2
- OR1S1 | c.364G>A p.V122I | Missense Mutation (SNP) | VAF 59/210 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs147498041; called by muse, mutect2, varscan2
- PHKA1 | c.2237C>T p.S746F | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.218); catalogued as COSV59807138; called by muse, mutect2
- POM121L12 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 56/258 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.573); catalogued as rs565383229, COSV68693234; called by muse, mutect2, varscan2
- SYNE1 | c.4231C>A p.Q1411K (on ENST00000367255 / NM_182961.4; = p.Q1418K on NM_033071.3) | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55006330, COSV99574077; called by muse, mutect2
- THADA | c.3922G>C p.D1308H | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV57694794; called by muse, mutect2
- AXIN2 | c.2198G>A p.G733E | Missense Mutation (SNP) | VAF 14/410 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.172); called by muse, mutect2
- CDH1 | c.169_187del p.F57Dfs*20 | Frame Shift Del (DEL) | VAF 42/218 reads (19%) | called by mutect2, pindel, varscan2
- CDH8 | c.1994T>C p.I665T | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- NR2F6 | c.863A>C p.Q288P | Missense Mutation (SNP) | VAF 98/363 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- OR4N2 | c.488T>A p.I163N | Missense Mutation (SNP) | VAF 47/231 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- PAG1 | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBX3 | c.630_633del p.N211Tfs*31 (on ENST00000257566 / NM_016569.4; = p.N211Tfs*11 on NM_005996.4) | Frame Shift Del (DEL) | VAF 173/629 reads (28%) | called by mutect2, pindel, varscan2
- TRIM62 | c.803A>T p.D268V | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TUBB4B | c.199G>C p.D67H | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UCN2 | c.221T>C p.L74P | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZKSCAN1 | c.577C>T p.R193* | Nonsense Mutation (SNP) | VAF 58/122 reads (48%) | called by muse, mutect2, varscan2
- ZNF148 | c.924A>C p.K308N | Missense Mutation (SNP) | VAF 8/133 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.888); called by muse, mutect2
- AC020907.6 | c.126C>T p.L42= | Silent (SNP) | VAF 54/315 reads (17%) | catalogued as rs1156835276; called by muse, mutect2, varscan2
- HGF | c.1311G>A p.E437= | Silent (SNP) | VAF 16/341 reads (5%) | catalogued as COSV55956496; called by muse, mutect2
- PRKAB2 | c.138C>T p.F46= | Silent (SNP) | VAF 18/562 reads (3%) | catalogued as rs782792671; called by muse, mutect2
- TCIRG1 | c.2203C>T p.L735= | Silent (SNP) | VAF 50/222 reads (23%) | catalogued as rs746026450; called by muse, mutect2, varscan2
- ARMCX4 | c.1038+3909G>T | Intron (SNP) | VAF 19/153 reads (12%) | called by muse, mutect2, varscan2
- KLC2 | c.*482del | 3'UTR (DEL) | VAF 25/81 reads (31%) | called by mutect2, pindel*
- MATR3 | c.*1433C>T | 3'UTR (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2
- SLC25A46 | c.284-8del | Intron (DEL) | VAF 11/78 reads (14%) | catalogued as rs559871816; called by mutect2, varscan2
- SMAP2 | c.103+437G>A | Intron (SNP) | VAF 42/160 reads (26%) | called by muse, mutect2, varscan2
- TGFB2 | c.346+16314C>T | Intron (SNP) | VAF 14/288 reads (5%) | called by muse, mutect2
- TNPO2 | c.-13-243G>C | Intron (SNP) | VAF 3/20 reads (15%) | catalogued as rs1275333604; called by muse, mutect2
- TRMT10B | c.420+64T>C | Intron (SNP) | VAF 16/99 reads (16%) | called by muse, mutect2, varscan2
